Surgical pathology report (de-identified scan), TCGA case TCGA-OR-A5LG, project TCGA-ACC (Adrenocortical Carcinoma), tissue source site University of Michigan, specimen TCGA-OR-A5LG-01A (Primary Tumor).

[page 1 of 2]
ICD-0-3

Carcinoma, Adrenal Cortical 8370/3

Site: Adrenal Gland Cortex
C74.0

gW 2/6/13

Procedure: L adrenalectomy

Gross description: 7 x 6.5 x 4.5cm, 115g

Diagnosis: adrenocortical carcinoma, paradrenal LN free of tumor, KI67 20-30%, pT3
pN0 (0/1) pMx Rx

Reference Pathology: none

4/12/13 - per additional path, Weiss = 6.
Malignant.
for

Process - if case passes will request
more path - may not ship if not
malignant.

Diagnostic Discrepancy		/

[page 2 of 2]
Patient # from Tissue Source Site

Date of report

Date of Surgery/specimen collection

Site (confirmed to be adrenal) with laterality indicated
Left

Tumor size(s)
7x6.5x4.5

Histologic diagnosis
ACC

Lymph Node Status
0/1

Pathologic information
T3,N0(0/1),Mx

Weiss score
6

Source: NCI Genomic Data Commons file 106b7860-a932-41fe-b9bb-ff0e8f0e0537 (TCGA-OR-A5LG.DA704AB1-8D08-48EC-9F62-A6B5E69E4DC7.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).